Somatic mutation profile of tumor specimen TARGET-20-PASLTF-09A (aliquot TARGET-20-PASLTF-09A-02D) from TARGET case TARGET-20-PASLTF, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 16.9 years (6,157 days).
Specimen TARGET-20-PASLTF-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3741018c-d229-4f17-bca7-877950491f31.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASLTF-14A (Bone Marrow Normal), aliquot TARGET-20-PASLTF-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e7d3d8e-f6df-44a8-bcbd-c177becd568e

The open-access MAF lists 14 somatic variants for this specimen: 3 protein-altering or splice-affecting, 4 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 4, Silent 4, Missense Mutation 2, 5'UTR 1, 3'Flank 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LAMA1 | c.2672G>A p.G891E | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1054948060; called by muse, mutect2, varscan2
- NEFH | c.2569_2571del p.K857del | In Frame Del (DEL) | VAF 32/85 reads (38%) | catalogued as rs762969612; called by pindel, varscan2
- AHNAK | c.6943C>G p.P2315A | Missense Mutation (SNP) | VAF 132/279 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AHNAK | c.12810G>A p.K4270= | Silent (SNP) | VAF 169/289 reads (58%) | called by muse, mutect2, varscan2
- GIMAP8 | c.1368C>T p.N456= | Silent (SNP) | VAF 52/98 reads (53%) | catalogued as rs140969132; called by muse, mutect2, varscan2
- MAP2K2 | c.939G>T p.R313= | Silent (SNP) | VAF 51/116 reads (44%) | catalogued as rs397517417; ClinVar: likely benign; called by muse, mutect2, varscan2
- PTPRJ | c.363T>C p.P121= | Silent (SNP) | VAF 71/140 reads (51%) | catalogued as rs778898203; called by muse, mutect2, varscan2
- ALK | c.-211C>G | 5'UTR (SNP) | VAF 42/98 reads (43%) | catalogued as rs770650212; called by muse, varscan2
- AXIN1 | c.*575_*625delinsGCCAGCAGGGGCTGCCCGAGTCTGTTTTTCATGCGATGACACTTGTAC | 3'UTR (DEL) | VAF 22/93 reads (24%) | called by pindel, varscan2*
- BSN | c.*1850C>T | 3'UTR (SNP) | VAF 108/188 reads (57%) | catalogued as rs746898167; called by muse, varscan2
- FHDC1 | c.*19T>C | 3'UTR (SNP) | VAF 60/116 reads (52%) | catalogued as rs541583484; called by muse, mutect2, varscan2
- NONO | chrX:71283630 G>A | 5'Flank (SNP) | VAF 73/156 reads (47%) | called by muse, mutect2, varscan2
- NOS1 | c.*3179dup | 3'UTR (INS) | VAF 62/150 reads (41%) | catalogued as rs1278700271; called by mutect2, pindel, varscan2
- REV3L | chr6:111299042 ins TATT | 3'Flank (INS) | VAF 32/80 reads (40%) | catalogued as rs1554266931; called by mutect2, pindel, varscan2
